Somatic mutation profile of tumor specimen MP2PRT-PAVDSG-TMP1-A (aliquot MP2PRT-PAVDSG-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVDSG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,863 days).
Specimen MP2PRT-PAVDSG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba16c739-0f5f-45d4-9d06-c6df9cc326f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDSG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDSG-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c39b72c-0afc-41c6-becc-cde7e2352c28

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 95/284 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ELOVL2 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs748114809; called by muse, mutect2, varscan2
- GRIK4 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 153/364 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779324606, COSV70804351; called by muse, mutect2, varscan2
- TRRAP | c.7718C>T p.T2573M (on ENST00000359863 / NM_001244580.1; = p.T2555M on NM_003496.3) | Missense Mutation (SNP) | VAF 19/358 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs76587346, COSV62839015; called by muse, mutect2
- USH2A | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 122/237 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as rs781022362, COSV56403406; called by muse, mutect2, varscan2
- IGKV1D-8 | c.351del p.P118Pfs*? | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by pindel*, varscan2
- OTULIN | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2
- PDCD4 | c.689T>G p.V230G | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- PPP3R2 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRK | c.154T>G p.Y52D | Missense Mutation (SNP) | VAF 171/436 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- SLFN11 | c.1820T>C p.I607T | Missense Mutation (SNP) | VAF 96/373 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- TENM3 | c.7688G>A p.R2563Q | Missense Mutation (SNP) | VAF 206/428 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- BCO1 | c.906C>T p.D302= | Silent (SNP) | VAF 162/393 reads (41%) | catalogued as rs752967860, COSV50729422; called by muse, mutect2, varscan2
- FARP1 | c.1329C>T p.A443= | Silent (SNP) | VAF 217/542 reads (40%) | called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937679 ins CCCCCTC | 3'Flank (INS) | VAF 68/235 reads (29%) | called by mutect2, pindel, varscan2
